HCMI case HCM-EXPT-0891-C25 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Ductal and Lobular Neoplasms; Primary site: Pancreas.
https://portal.gdc.cancer.gov/cases/de8fb027-acbe-4edb-8882-ad56778a10b0

Demographics
Sex at birth: female; Year of birth: 1953.

Diagnoses (1)
1. Infiltrating duct carcinoma, NOS: ICD-O-3 morphology code: 8500/3; ICD-10 code: C25.0; Tissue or organ of origin: Pancreas, NOS; Site of resection or biopsy: Head of pancreas; Classification of tumor: primary; Age at diagnosis: 64.4 years (23,507 days); Prior treatment: No.
   Recorded as not given: neoadjuvant treatment (type not reported).

Biospecimens (1 sample; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample HCM-EXPT-0891-C25-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
  Slide HCM-EXPT-0891-C25-01A-01-S2-HE: Section location: Bottom; Percent tumor cells: 18; Percent tumor nuclei: 25; Percent normal cells: 0; Percent necrosis: 15; Percent stromal cells: 67; Percent lymphocyte infiltration: 25; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 0.
  Slide HCM-EXPT-0891-C25-01A-01-S1-HE: Section location: Top; Percent tumor cells: 22; Percent tumor nuclei: 65; Percent normal cells: 0; Percent necrosis: 11; Percent stromal cells: 67; Percent lymphocyte infiltration: 22; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 0.
